Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-6606, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-6606-01A (Primary Tumor).

PATIENT HISTORY:

Colon cancer.

PREOP DIAGNOSIS: Colon cancer.

POSTOP DIAGNOSIS: Same.

PROCEDURE: Laparoscopic right hemi-colectomy.

ADDENDA:**Addendum****Molecular Anatomic Pathology Testing:****Block 2D:**

- A. KRAS codon 12/13 mutation IDENTIFIED (Gly12Val).

Note:

The quantity and quality of isolated DNA was acceptable for testing.

The predictive value of KRAS mutation in colorectal cancer patients treated with cetuximab (anti-EGFR monoclonal antibody) chemotherapy has recently been reported¹. Mutations in the KRAS codon 12/13 gene were found to be associated with resistance to cetuximab therapy, worse prognosis and poor survival in patients with metastatic colorectal cancer.¹⁻⁴ However, not all tumors reveal such a correlation, therefore the presence of KRAS mutations should be interpreted in the context of the cytologic and histologic findings and the patient's clinical history.

Addendum**Molecular Anatomic Pathology Testing:****Block 2D:**

- A. No microsatellite instability detected (Microsatellite stable).

Note:

The five NCI recommended dinucleotide and mononucleotide polymorphisms were utilized to assess for microsatellite instability (MSI) by PCR. None of five markers showed evidence of microsatellite instability.

High-level MSI may have prognostic implications, and patients with these tumors may be at risk for Hereditary Non-Polyposis Colorectal Carcinoma syndrome (HNPCC or Lynch Syndrome)(1-6). Genetic testing for germline mutations associated with that syndrome is indicated in patients with high-level MSI, after appropriate informed consent and genetic counseling (1). If clinical suspicion for HNPCC is very high, genetic testing may be appropriate even in cases with microsatellite stable lesions.

FINAL DIAGNOSIS:**PART 1: LIVER, BIOPSY –**

METASTATIC ADENOCARCINOMA TO LIVER.

PART 2: COLON, RIGHT, RIGHT HEMICOLECTOMY –

- A. INVASIVE MODERATELY DIFFERENTIATED COLONIC ADENOCARCINOMA.

- a. TUMOR MEASURES 8.0 CM IN GREATEST DIMENSION.

- b. TUMOR INVADÉS THROUGH THE MUSCULARIS PROPRIA AND EXTENSIVELY INVOLVES PERICOLONIC ADIPOSE TISSUE AND THE VISCERAL PERITONEAL SURFACE AND INVADÉS INTO THE MUSCULARIS PROPRIA OF A PORTION OF SMALL INTESTINE.

- c. ANGIOLYMPHATIC INVASION IS IDENTIFIED.

- d. pT4, N2, M1.

- B. MARGINS OF RESECTION ARE BENIGN.

- C. METASTATIC ADENOCARCINOMA IS PRESENT IN TEN OF SEVENTEEN LYMPH NODES (10/17).

- D. APPENDIX IS PRESENT AND SHOWS SEROSAL INVOLVEMENT BY THE COLONIC ADENOCARCINOMA.

- E. SEPARATE TUBULAR ADENOMA (1.0 CM).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS**

SPECIMEN TYPE:	Right hemicolectomy
TUMOR SITE:	Cecum
TUMOR CONFIGURATION:	Infiltrative
TUMOR SIZE:	Greatest dimension: 6.5 cm
INTACTNESS OF MESORECTUM:	Not applicable
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	Low-grade (well to moderately differentiated)
PATHOLOGIC STAGING (pTNM):	pT4b pN2 Number of nodes examined: 17 Number of nodes involved: 10 pM1 Site(s): liver Treatment: Untreated
MARGINS:	Proximal margin uninvolved by invasive carcinoma Distal margin uninvolved by invasive carcinoma Circumferential (radial) margin - Not applicable Mesenteric margin uninvolved by invasive carcinoma
ANGIOLYMPHATIC INVASION:	Present
PERINEURAL INVASION:	Present
TUMOR BORDER CONFIGURATION:	Infiltrating
ADDITIONAL TUMOR CHARACTERISTICS:	None

Source: NCI Genomic Data Commons file c11d80d0-401c-4b44-bd26-5bdc9ec463a9 (TCGA-AZ-6606.9E1AC172-4EB9-4566-86FE-FE01648C4D8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).